Gene-level copy-number profile of tumor specimen TCGA-V1-A8MF-01A from TCGA case TCGA-V1-A8MF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.5b8f9a27-8a46-473f-b20b-62fdb8955cfa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A8MF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2ff7bff-f71b-4af3-8e1e-14f2aea3a0a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,026; copy number 2: 52,268; copy number 3: 964; copy number 4: 894; copy number 5: 542; copy number 6: 123.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A8MF-01A-11D-A363-01): tumor purity 0.64, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 665 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:56,445,807–56,556,513, 1 gene, copy number 5 (within-gene range 4–5): AC012349.1.
- chr8:56,496,048–57,126,762, 8 genes, copy number 5: LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266.
- chr8:60,876,969–77,537,290, 250 genes, copy number 5 (broad region; genes not listed).
- chr8:79,747,351–99,877,580, 334 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:101,177,878–103,501,895, 69 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:103,559,099–103,769,029, 3 genes, copy number 5: PTMAP15, AC007751.1, AC090686.1.

Autosomal genes at a single copy (total copy number 1): 2,646. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
